Surgical pathology report (de-identified scan), TCGA case TCGA-55-8512, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8512-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

DIAGNOSIS:

A. Lung, right lower lobe; lobectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma arising within the background of bronchial alveolar carcinoma.
2. Histologic grade: Well differentiated.
3. Tumor site: Right lower lobe.
4. Tumor focality: Unifocal.
5. Tumor size: 1.7 x 1.5 x 1.1 cm.
6. Visceral pleural invasion: Not identified.
7. Lymphovascular space invasion: Present.
8. Tumor extension: Tumor limited to pulmonary parenchyma.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Tumor distance from bronchial margin: 2.6 cm.
2. Tumor distance from parenchymal (stapled) margin: 4.1 cm.
3. Tumor distance from pleural surface: 0.8 cm.

Lymph Node Status:

1. Total number of lymph nodes received: 8.
One peribronchial node.
Four hilar nodes.
Three level 9 nodes, see specimen B.
2. Total number of lymph nodes containing metastatic carcinoma: 2 (2/8).

Other:

1. Lung cancer molecular panel pending, results will be reported as an addendum.
2. pTNM stage: pT1 N1.

B. Level 9 lymph node; excision:

Metastatic carcinoma present in one of three lymph nodes (1/3).

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right lower lobe
- B. Level IX lymph node

SPECIMEN DATA

GROSS DESCRIPTION:

A. Received in formalin labeled _____ and right lower lobe, is a 239 gm, 15.8 x 10.5 x 4.3 cm, lung lobe with a 0.4 cm segment of attached bronchial. The specimen cannot be oriented.

[page 2 of 2]
The pleura is shaggy and tan-red to gray-purple with three linear staple lines near the hilum, ranging from 3.1 cm to 5.5 cm. The staple lines are removed and the underlying parenchyma is inked blue.

The cut surface consists of a 1.7 x 1.5 x 1.1 cm, ill-defined tan mass, 1.6 cm from the pleura. The mass is 2.6 cm from the bronchial margin and 4.1 cm from the closest staple line.

The remainder of the cut surface consists of spongy red-brown parenchyma. No additional lesions are identified. No obvious intraparenchymal lymph nodes are identified.

There are four irregular gray-black firm tissues consistent with probable lymph node at the hilum, ranging from 0.4 x 0.3 x 0.2 cm to 0.8 x 0.5 x 0.3 cm. The specimen is inked, serially sectioned, and representative sections are submitted as labeled: 1 -- bronchial vascular margins (en face); 2 -- mass to pleura; 3-5 -- remainder of identifiable mass, entirely submitted; 6-8 -- uninvolved parenchyma to include stapled areas (perpendicular); 9 -- four whole hilar probable lymph nodes. The blocks are labeled 1-9. Also received in the same container are a blue, a green, and a yellow cassette labeled [REDACTED] for genomics research study.

B. Received in formalin labeled [REDACTED] y and level IX lymph node, are three irregular gray-black firm tissues consistent with probable lymph node with attached adipose tissue, ranging from 0.4 x 0.3 x 0.2 cm to 0.8 x 0.5 x 0.3 cm. The specimen is submitted in its entirety as labeled: 1 -- two whole probable lymph nodes; 2 -- one lymph node, bisected. The blocks are labeled 1-3.

Source: NCI Genomic Data Commons file b0c94e79-e329-4deb-bd97-eb2e5be8a141 (TCGA-55-8512.5146C0EB-7BBB-4160-A52F-C0D0EE34FF83.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).